Surgical pathology report (de-identified scan), TCGA case TCGA-85-7843, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-7843-01A (Primary Tumor).

[page 1 of 2]
[Redacted]

[Redacted] Case ID		OC ID	Gross Description	Microscopic Description	Diagnosis Details	Comments
[Redacted]		[Redacted]				

[page 2 of 2]
Formatted Path Report

LUNG TISSUE CHECKLIST

Specimen type: Pulmonectomy
Tumor site: Lung
Tumor size: 4.5 cm
Histologic type: Squamous cell carcinoma
Histologic grade: Moderately differentiated
Tumor extent: Tumor in main bronchus
Other tumor nodules: Not specified
Lymph nodes: 2/7 positive for metastasis (Intrathoracical 2/7)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Margins: Not specified
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

OpenClinica ID	Date of Procurement	Laterality
		Left-upper

Source: NCI Genomic Data Commons file 8e2d014d-9b84-43ff-af8b-7afc113092a1 (TCGA-85-7843.E48C2D72-9664-44CF-9D54-684490E86544.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).